Somatic mutation profile of tumor specimen TCGA-J2-A4AG-01A (aliquot TCGA-J2-A4AG-01A-11D-A24D-08) from TCGA case TCGA-J2-A4AG, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.3 years (24,224 days).
Specimen TCGA-J2-A4AG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4eba2e38-67a5-4bc2-a1e5-a29f44156a59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J2-A4AG-10A (Blood Derived Normal), aliquot TCGA-J2-A4AG-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/895ed862-fb75-45eb-8251-a503fc5e3af2

The open-access MAF lists 86 somatic variants for this specimen: 61 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 24, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 2, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS12 | c.4188C>A p.D1396E | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV61265622; called by muse, mutect2, varscan2
- ARRDC3 | c.280+1G>A p.X94_splice | Splice Site (SNP) | VAF 6/104 reads (6%) | catalogued as COSV99475352; called by muse, mutect2
- BACH2 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758480618, COSV100000319; called by muse, mutect2
- CC2D1A | c.2333G>T p.R778L | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54310139, COSV99582967; called by muse, mutect2
- CCDC9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99699780, COSV99699992; called by muse, mutect2
- CDH7 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99064582; called by muse, mutect2, varscan2
- CDK18 | c.791G>T p.G264V (on ENST00000506784 / NM_212503.3; = p.G234V on NM_002596.4) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100774074; called by muse, mutect2, varscan2
- CLK2 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV100751900; called by muse, mutect2, varscan2
- CMTR2 | c.1490del p.L497Wfs*9 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as COSV57602744; called by mutect2, pindel, varscan2
- CPD | c.2887A>T p.T963S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99853081; called by muse, mutect2, varscan2
- CROT | c.1636G>T p.V546F | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV100519612; called by muse, mutect2, varscan2
- CSMD3 | c.7436C>G p.P2479R (on ENST00000297405 / NM_001363185.1; = p.P2375R on NM_052900.3) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99841256; called by muse, mutect2, varscan2
- CSMD3 | c.4828C>A p.H1610N (on ENST00000297405 / NM_001363185.1; = p.H1506N on NM_052900.3) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.777); catalogued as COSV52328561, COSV99841260; called by muse, mutect2, varscan2
- CTSO | c.932-1G>T p.X311_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV101467869; called by muse, mutect2, varscan2
- CXCL6 | c.55T>C p.C19R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99884979; called by muse, mutect2
- DAGLA | c.1472C>A p.T491N | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99944359, COSV99944554; called by muse, mutect2, varscan2
- DISP1 | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.262); catalogued as rs576683817, COSV99451614; called by muse, mutect2, varscan2
- DYNC2H1 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 27/178 reads (15%) | catalogued as COSV100519143; called by muse, mutect2, varscan2
- EDIL3 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99678082; called by muse, mutect2
- EYS | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.049); catalogued as COSV100676853; called by muse, mutect2, varscan2
- FLNC | c.5735G>T p.G1912V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368432; called by muse, mutect2, varscan2
- FOLH1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs772709942, COSV57045358; called by muse, mutect2, varscan2
- GLUL | c.581A>T p.N194I | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100092129; called by muse, mutect2, varscan2
- HAPLN1 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99165084; called by muse, mutect2, varscan2
- HOXD10 | c.848_849del p.K283Rfs*18 | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | catalogued as rs1242151127; called by mutect2, varscan2
- HSF5 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV100090505; called by muse, mutect2
- IFNA7 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99497551; called by muse, mutect2
- L1CAM | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649357; called by muse, mutect2
- LHCGR | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as COSV104399842, COSV54291979, COSV99683987; called by muse, mutect2
- LRP1B | c.9334G>C p.E3112Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101258381, COSV67211217; called by muse, mutect2, varscan2
- MAX | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99408560; called by muse, mutect2, varscan2
- MYH8 | c.4321G>A p.A1441T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV101238529; called by muse, mutect2, varscan2
- MYRF | c.2945G>A p.G982D (on ENST00000278836 / NM_001127392.3; = p.G947D on NM_013279.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV99607460; called by muse, mutect2, varscan2
- NID2 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99356944; called by muse, mutect2, varscan2
- OR5L2 | c.715T>A p.S239T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101004364; called by muse, mutect2, varscan2
- P3H3 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV99300802, COSV99301476; called by mutect2, varscan2
- PCDHA12 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100252378; called by muse, mutect2, varscan2
- PDE4DIP | c.3381C>G p.S1127R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV100520602; called by muse, mutect2, varscan2
- PHRF1 | c.1441G>T p.V481L (on ENST00000264555 / NM_001286581.2; = p.V480L on NM_020901.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs372144693, COSV99212734; called by muse, mutect2
- POLA2 | c.1559T>C p.I520T | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99641106; called by muse, mutect2
- PZP | c.2792C>A p.A931D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV99738728; called by muse, mutect2, varscan2
- RAB3IP | c.1138C>T p.R380W (on ENST00000550536 / NM_175623.4; = p.R364W on NM_022456.5) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs773832345, COSV56082815; called by muse, mutect2, varscan2
- RGS5 | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100009206; called by muse, mutect2, varscan2
- SLC20A2 | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1320560354, COSV100646150; called by muse, mutect2, varscan2
- SLC35D1 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99338358; called by muse, mutect2
- TBC1D8B | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99344780; called by muse, mutect2
- TBX5 | c.1134C>A p.C378* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100091658; called by muse, mutect2, varscan2
- TUBGCP3 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV99997035; called by muse, mutect2
- UBR4 | c.11295C>A p.C3765* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | catalogued as COSV100921361; called by muse, mutect2, varscan2
- UNC5D | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99777298; called by muse, mutect2, varscan2
- Z84488.1 | c.846T>A p.S282R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV100889461; called by muse, mutect2, varscan2
- ZMYM3 | c.2330C>A p.S777* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100078157; called by muse, mutect2
- ZNF354A | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100234575; called by muse, mutect2, varscan2
- ZNF543 | c.509A>G p.K170R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100386859; called by muse, mutect2, varscan2
- ZNF704 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.197); catalogued as COSV100589707, COSV59922233; called by muse, mutect2
- ZNF99 | c.1298C>A p.A433D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV68054948, COSV68054977; called by muse, mutect2, varscan2
- ADGRV1 | c.17821del p.L5941* | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- IGKV3-7 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- PCDHB11 | c.2326del p.A776Qfs*38 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- SLC35G3 | c.120del p.L41Wfs*127 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- CDH7 | c.1989G>T p.T663= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV59898764; called by muse, mutect2, varscan2
- CROT | c.1635G>T p.L545= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV100519611; called by muse, mutect2, varscan2
- CYP7A1 | c.1110C>T p.F370= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100052546; called by muse, mutect2
- DSG4 | c.459C>T p.N153= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs749138368, COSV100356160; called by muse, mutect2, varscan2
- EBNA1BP2 | c.816G>T p.R272= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99356041; called by muse, mutect2, varscan2
- FCHO1 | c.615G>A p.E205= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1350007162, COSV53181459; called by muse, mutect2, varscan2
- GPRC5B | c.144G>C p.L48= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1229224218, COSV100315213; called by muse, mutect2, varscan2
- ITIH6 | c.1242C>A p.V414= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99513667; called by muse, mutect2
- KATNIP | c.2055T>A p.T685= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV99851619; called by muse, mutect2
- MAX | c.213C>T p.I71= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs777274451, COSV99408563; called by muse, mutect2, varscan2
- MMEL1 | c.408C>T p.Y136= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99984151; called by mutect2, varscan2
- MUC17 | c.1293C>T p.S431= | Silent (SNP) | VAF 54/382 reads (14%) | catalogued as COSV60301679; called by muse, mutect2, varscan2
- OR14I1 | c.579A>G p.V193= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs1336722662, COSV100700517; called by muse, mutect2, varscan2
- OR2T33 | c.72C>A p.V24= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV58818628; called by muse, mutect2, varscan2
- PPRC1 | c.2811G>C p.L937= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs944506469; called by mutect2, varscan2
- RFWD3 | c.2043C>T p.I681= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100736280; called by muse, mutect2, varscan2
- SLC24A3 | c.1056C>T p.I352= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100042167; called by muse, mutect2
- SLC5A1 | c.567C>A p.A189= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99833603; called by muse, mutect2
- SNTG1 | c.516T>C p.S172= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99384947; called by muse, mutect2
- TMEM119 | c.633C>A p.G211= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101219521; called by muse, mutect2, varscan2
- TSHZ3 | c.1446C>T p.D482= | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as rs745403920, COSV53664438, COSV53666789; called by muse, mutect2, varscan2
- UBP1 | c.1071A>G p.S357= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99372794; called by muse, mutect2, varscan2
- USH2A | c.4878A>T p.I1626= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV100238860; called by muse, mutect2, varscan2
- ZEB2 | c.2869C>A p.R957= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV57955107, COSV57965320; called by muse, mutect2, varscan2
- DCHS2 | n.2446C>A | RNA (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100252532; called by muse, mutect2, varscan2
